Somatic mutation profile of tumor specimen 0E1NZY from CCDI case PBCWJL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female.
Specimen 0E1NZY: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0f0d7989-abac-40a8-81ae-dde874620d75.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E1NYQ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d995a30e-5e61-4619-ad76-c48bc0944e1e

The open-access MAF lists 5 somatic variants for this specimen: 5 protein-altering or splice-affecting.
By variant classification: Missense Mutation 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGEF15 | c.52C>T p.R18W | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs200187886; called by muse, mutect2, varscan2
- MYO15A | c.997G>A p.E333K | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.038); catalogued as rs772104371, COSV99231379; called by muse, mutect2, varscan2
- ARHGEF28 | c.4249C>G p.L1417V | Missense Mutation (SNP) | VAF 44/296 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- OTOA | c.115A>G p.M39V | Missense Mutation (SNP) | VAF 38/292 reads (13%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ZNF763 | c.218A>T p.E73V (on ENST00000358987 / NM_001367172.2; = p.E76V on NM_001012753.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/290 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
